Somatic mutation profile of tumor specimen TCGA-13-2061-01A (aliquot TCGA-13-2061-01A-01D-1526-09) from TCGA case TCGA-13-2061, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.0 years (21,543 days).
Specimen TCGA-13-2061-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58b04a73-485b-423c-80f5-6fb7499a35af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-2061-10A (Blood Derived Normal), aliquot TCGA-13-2061-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56162007-db60-4ce4-9e68-4f748466af68

The open-access MAF lists 121 somatic variants for this specimen: 99 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 87, Silent 22, In Frame Del 4, Frame Shift Del 4, Splice Region 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 279/359 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.3527G>A p.R1176K | Missense Mutation (SNP) | VAF 77/452 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1393984875, COSV62321981; called by muse, mutect2, varscan2
- ACSBG2 | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 56/551 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as COSV99397609; called by muse, mutect2
- ADAMTS20 | c.5012G>C p.G1671A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67129157, COSV67138607; called by muse, mutect2, varscan2
- AGO1 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 130/374 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs758951181, COSV64594852; called by muse, mutect2, varscan2
- AK5 | c.596T>C p.I199T (on ENST00000354567 / NM_174858.3; = p.I173T on NM_012093.4) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58355080; called by muse, mutect2, varscan2
- ALPK3 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as COSV51931315; called by muse, mutect2, varscan2
- APOBEC3G | c.644G>C p.R215P | Missense Mutation (SNP) | VAF 131/231 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs1195105163, COSV68470131; called by muse, mutect2, varscan2
- ATP1A2 | c.1784C>A p.A595D | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV63402910, COSV63404762; called by muse, mutect2, varscan2
- B4GALT7 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV50352863; called by muse, mutect2, varscan2
- BPIFB3 | c.1087A>G p.N363D | Missense Mutation (SNP) | VAF 201/581 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1420004124, COSV64956994; called by muse, mutect2, varscan2
- C3 | c.1104G>T p.M368I | Missense Mutation (SNP) | VAF 32/638 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV99837130; called by muse, mutect2
- CASP8 | c.283A>T p.R95W | Missense Mutation (SNP) | VAF 89/168 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV51847863; called by muse, mutect2, varscan2
- CD2 | c.248C>A p.T83K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV65643413; called by muse, mutect2, varscan2
- CD2 | c.915G>C p.Q305H | Missense Mutation (SNP) | VAF 161/402 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV65643991, COSV65644062; called by muse, mutect2, varscan2
- COL11A1 | c.911A>T p.D304V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.329); catalogued as rs748683069, COSV62176530; called by muse, mutect2, varscan2
- COL4A5 | c.4445A>C p.Q1482P | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.225); catalogued as COSV60358484; called by muse, mutect2, varscan2
- COMMD4 | c.278T>A p.L93Q | Missense Mutation (SNP) | VAF 93/296 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51190245; called by muse, mutect2, varscan2
- CPS1 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51805288; called by muse, mutect2, varscan2
- CYP11B2 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 242/495 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100011302, COSV59995426; called by muse, mutect2
- DCTN1 | c.3364T>A p.S1122T | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV62619920; called by muse, mutect2, varscan2
- DDC | c.373A>T p.M125L | Missense Mutation (SNP) | VAF 227/634 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs564352252, COSV63564471; called by muse, mutect2, varscan2
- DMXL2 | c.2693A>T p.E898V | Missense Mutation (SNP) | VAF 102/553 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51842675; called by muse, mutect2, varscan2
- DNAH2 | c.6976T>C p.C2326R | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs764941700, COSV101209546; called by muse, mutect2
- DOCK2 | c.1303T>G p.F435V | Missense Mutation (SNP) | VAF 102/541 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV56948765; called by muse, mutect2, varscan2
- DUSP21 | c.520G>C p.G174R | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100173606, COSV59133727; called by muse, mutect2, varscan2
- EPRS1 | c.737A>G p.E246G | Missense Mutation (SNP) | VAF 147/346 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.243); catalogued as COSV65097768; called by muse, mutect2, varscan2
- ERN2 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs1325407290, COSV99891514; called by muse, mutect2
- F7 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs771335282, CM002763, COSV60645501; called by muse, mutect2
- FBN3 | c.7423G>A p.G2475S | Missense Mutation (SNP) | VAF 148/194 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758643531, COSV54456372; called by muse, mutect2, varscan2
- G6PC2 | c.493T>C p.C165R | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56371772; called by muse, mutect2, varscan2
- GARRE1 | c.1343T>C p.V448A | Missense Mutation (SNP) | VAF 30/682 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as COSV100209682; called by muse, mutect2
- GATA3 | c.1223C>A p.P408H | Missense Mutation (SNP) | VAF 211/491 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV60516666; called by muse, mutect2, varscan2
- GPS2 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100223251; called by muse, mutect2
- GTPBP8 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV55606160, COSV55607483; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 120/370 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV100676528; called by muse, mutect2
- HPD | c.516A>T p.K172N | Missense Mutation (SNP) | VAF 131/463 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as COSV56641439; called by muse, mutect2, varscan2
- IGSF9 | c.1213G>A p.G405R (on ENST00000368094 / NM_001135050.2; = p.G389R on NM_020789.4) | Missense Mutation (SNP) | VAF 62/420 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753817794, COSV63639301; called by muse, mutect2, varscan2
- INO80 | c.3788A>T p.E1263V | Missense Mutation (SNP) | VAF 240/326 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62736983; called by muse, mutect2, varscan2
- ITGA7 | c.3287T>A p.L1096Q (on ENST00000555728; = p.L1052Q on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 189/451 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57693219; called by muse, mutect2, varscan2
- KCNQ3 | c.283C>G p.R95G | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1418381991, COSV101196342; called by muse, mutect2
- LAMC3 | c.4377G>T p.R1459= | Splice Region (SNP) | VAF 85/118 reads (72%) | catalogued as COSV62653705; called by muse, mutect2, varscan2
- LGALS4 | c.780G>T p.E260D | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV100313351; called by muse, mutect2
- LRRC61 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as rs1218684572, COSV56230978; called by muse, mutect2, varscan2
- MDN1 | c.13103C>G p.P4368R | Missense Mutation (SNP) | VAF 127/474 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65519052; called by muse, mutect2, varscan2
- MED23 | c.3106G>A p.D1036N | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV100645341; called by muse, mutect2
- MFRP | c.346A>T p.I116F (on ENST00000449574; = p.I492F on NM_031433.4) | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100264908; called by muse, mutect2
- MFRP | c.197T>G p.M66R (on ENST00000449574; = p.M442R on NM_031433.4) | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV100793524; called by muse, mutect2
- MIER3 | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV61229307, COSV61229665; called by muse, mutect2, varscan2
- MRGPRX3 | c.185C>A p.S62Y | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66933404; called by muse, mutect2, varscan2
- MS4A3 | c.156G>T p.G52= | Splice Region (SNP) | VAF 29/122 reads (24%) | catalogued as COSV53935456; called by muse, mutect2, varscan2
- MYO9A | c.5750G>A p.G1917E | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV61848883; called by muse, mutect2, varscan2
- NAA40 | c.181C>G p.R61G | Missense Mutation (SNP) | VAF 44/508 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100624231, COSV58160920; called by muse, mutect2
- NRROS | c.1968C>G p.I656M | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.177); catalogued as COSV60745118; called by muse, mutect2, varscan2
- OR10C1 | c.737T>A p.L246Q (on ENST00000622521; = p.L244Q on NM_013941.3) | Missense Mutation (SNP) | VAF 133/540 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65822422; called by muse, mutect2, varscan2
- OR10Q1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.948); catalogued as COSV57470024; called by muse, mutect2, varscan2
- OR1S1 | c.963A>T p.K321N | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV58706182, COSV58707037; called by muse, mutect2, varscan2
- PAIP1 | c.484G>C p.V162L | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV100166728; called by muse, mutect2
- PAXIP1 | c.1168A>G p.S390G | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as rs1450623786; called by muse, mutect2
- PCNX1 | c.2619C>G p.H873Q | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs761536219, COSV53103422; called by muse, mutect2
- PIGG | c.1604C>A p.T535N (on ENST00000453061 / NM_001127178.3; = p.T527N on NM_017733.4) | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV56317005; called by muse, mutect2, varscan2
- PKHD1 | c.9635T>C p.F3212S | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61898806; called by muse, mutect2
- PKP1 | c.1275A>T p.Q425H | Missense Mutation (SNP) | VAF 21/282 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99825628; called by muse, mutect2
- PLD2 | c.1091G>T p.W364L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200410286, COSV54004496; called by muse, mutect2, varscan2
- POU3F2 | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60408635; called by muse, mutect2, varscan2
- PRDM7 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 198/253 reads (78%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs765946643, COSV57986306, COSV57987708; called by muse, mutect2, varscan2
- RAB10 | c.218C>G p.T73S | Missense Mutation (SNP) | VAF 98/184 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53088785; called by muse, mutect2, varscan2
- REXO1 | c.1361C>G p.P454R | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.54); PolyPhen benign (0.05); catalogued as COSV50075745; called by muse, mutect2, varscan2
- RTEL1 | c.1428C>G p.I476M | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58891812; called by muse, mutect2, varscan2
- SERBP1 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 14/187 reads (7%) | catalogued as COSV100769107, COSV100769143; called by muse, mutect2
- SIRT5 | c.766C>G p.P256A | Missense Mutation (SNP) | VAF 159/702 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63080011; called by muse, mutect2, varscan2
- STARD8 | c.454A>T p.S152C | Missense Mutation (SNP) | VAF 129/176 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52923384; called by muse, mutect2, varscan2
- SYNE1 | c.11800G>T p.V3934F | Missense Mutation (SNP) | VAF 171/223 reads (77%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as COSV54935744; called by muse, mutect2, varscan2
- TACC2 | c.2465C>A p.P822H | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV100553501; called by muse, mutect2
- TACC2 | c.2769G>T p.W923C | Missense Mutation (SNP) | VAF 29/390 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV100553503; called by muse, mutect2
- TACC2 | c.7450A>C p.M2484L (on ENST00000334433; = p.M562L on NM_006997.4) | Missense Mutation (SNP) | VAF 58/774 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV99587561; called by muse, mutect2
- TCF7L1 | c.185T>A p.L62Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56397118; called by muse, mutect2, varscan2
- TUBA8 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 114/351 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as rs754515296, COSV57812607; called by muse, mutect2, varscan2
- TYRO3 | c.282C>G p.S94R | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV55481425, COSV99778020; called by muse, mutect2
- UBAP2 | c.119G>C p.R40P | Missense Mutation (SNP) | VAF 99/129 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100671697, COSV62545738; called by muse, mutect2, varscan2
- UGT1A4 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 160/357 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.173); catalogued as COSV59384781; called by muse, mutect2, varscan2
- VSTM2L | c.236G>C p.W79S | Missense Mutation (SNP) | VAF 118/269 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV65095677; called by muse, mutect2, varscan2
- WDR91 | c.1229C>G p.S410C | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60369590; called by muse, mutect2
- YIPF3 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.04); catalogued as COSV58304046; called by muse, mutect2, varscan2
- ZNF416 | c.1704C>G p.H568Q | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99543923; called by muse, mutect2
- ZNF442 | c.296G>T p.S99I | Missense Mutation (SNP) | VAF 181/411 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV54420948; called by muse, mutect2, varscan2
- ZNF536 | c.1868C>G p.P623R | Missense Mutation (SNP) | VAF 113/254 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as COSV62821038; called by muse, mutect2, varscan2
- ZNF653 | c.1172A>G p.E391G | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV53402376; called by muse, mutect2, varscan2
- CDC42BPG | c.3827_3840delinsGGTTT p.L1276_L1280delinsRF | In Frame Del (DEL) | VAF 11/72 reads (15%) | called by pindel, varscan2*
- DDX5 | c.1545_1572del p.D515Efs*65 | Frame Shift Del (DEL) | VAF 40/62 reads (65%) | called by mutect2, pindel, varscan2
- DNAJB4 | c.338del p.G113Efs*15 | Frame Shift Del (DEL) | VAF 73/204 reads (36%) | called by mutect2, pindel, varscan2
- EHMT2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- FCGBP | c.6507C>G p.H2169Q | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.062); called by muse, mutect2
- G6PC2 | c.205_217del p.L69Gfs*55 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- HOOK3 | c.1155_1169del p.E385_A389del | In Frame Del (DEL) | VAF 45/182 reads (25%) | called by mutect2, pindel, varscan2
- IFT80 | c.1517-5_1517-2del p.X506_splice | Splice Site (DEL) | VAF 51/146 reads (35%) | called by mutect2, pindel, varscan2
- MFSD3 | c.459_493del p.L154Tfs*64 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel
- NIM1K | c.901_909del p.L301_R303del | In Frame Del (DEL) | VAF 35/196 reads (18%) | called by mutect2, pindel, varscan2
- RNF220 | c.1041_1049del p.E348_N350del | In Frame Del (DEL) | VAF 165/378 reads (44%) | called by mutect2, pindel, varscan2
- ADM2 | c.330T>C p.C110= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- DECR1 | c.39C>T p.S13= | Silent (SNP) | VAF 41/152 reads (27%) | catalogued as rs1423995893, COSV55167594; called by muse, mutect2, varscan2
- DSEL | c.3432T>A p.P1144= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1351185963, COSV100025994; called by muse, mutect2
- FBXO33 | c.375G>T p.L125= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as COSV53233684; called by muse, mutect2, varscan2
- GCKR | c.945C>G p.T315= | Silent (SNP) | VAF 127/447 reads (28%) | catalogued as COSV53107010; called by muse, mutect2, varscan2
- ITGB5 | c.345C>G p.A115= | Silent (SNP) | VAF 87/160 reads (54%) | catalogued as COSV56147540; called by muse, mutect2, varscan2
- LAMB1 | c.3828C>G p.S1276= | Silent (SNP) | VAF 18/514 reads (4%) | catalogued as COSV99741538; called by muse, mutect2
- LTN1 | c.4209T>C p.H1403= | Silent (SNP) | VAF 39/50 reads (78%) | catalogued as COSV63733338; called by muse, mutect2, varscan2
- NRSN1 | c.321G>A p.Q107= | Silent (SNP) | VAF 70/293 reads (24%) | catalogued as COSV65893767, COSV65893997; called by muse, mutect2, varscan2
- OR9G4 | c.585C>T p.Y195= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as rs149148369; called by muse, mutect2, varscan2
- PHF7 | c.750C>A p.A250= | Silent (SNP) | VAF 121/179 reads (68%) | catalogued as COSV59979052; called by muse, mutect2, varscan2
- PRKD2 | c.2436G>A p.T812= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as rs192674557, COSV99354574; called by muse, mutect2
- PVRIG | c.75C>A p.T25= | Silent (SNP) | VAF 95/252 reads (38%) | catalogued as COSV52780706; called by muse, mutect2, varscan2
- ROR1 | c.1335C>T p.H445= | Silent (SNP) | VAF 113/390 reads (29%) | catalogued as rs753466455, COSV64284958, COSV64292825; called by muse, mutect2, varscan2
- SERTAD4 | c.888C>G p.P296= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV100882639, COSV65398992; called by muse, mutect2, varscan2
- SLC4A11 | c.1944G>A p.A648= | Silent (SNP) | VAF 109/174 reads (63%) | catalogued as rs776477379, COSV66260943; called by muse, mutect2, varscan2
- SLIT1 | c.582C>T p.T194= | Silent (SNP) | VAF 515/726 reads (71%) | catalogued as rs1472742515, COSV56585347; called by muse, mutect2, varscan2
- TBX2 | c.717C>T p.A239= | Silent (SNP) | VAF 131/178 reads (74%) | catalogued as COSV53598133; called by muse, mutect2, varscan2
- TGM2 | c.2061C>T p.A687= | Silent (SNP) | VAF 137/326 reads (42%) | catalogued as COSV63931218; called by muse, mutect2, varscan2
- TRAPPC9 | c.340C>A p.R114= | Silent (SNP) | VAF 93/353 reads (26%) | catalogued as COSV66895072; called by muse, mutect2, varscan2
- TTLL4 | c.198G>A p.G66= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as COSV99293688; called by muse, mutect2
- TYRP1 | c.231T>C p.P77= | Silent (SNP) | VAF 65/103 reads (63%) | catalogued as COSV66357791; called by muse, mutect2, varscan2
